Somatic mutation profile of tumor specimen 0DRU3V from CCDI case PBCHDM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,713 days).
Specimen 0DRU3V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaeaa6f4-7a67-4da0-9bc4-3da5063c6542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRU3P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbe1fae-0553-4a3d-beae-83bd9c3ae6a4

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Intron 4, Splice Site 3, Silent 3, Frame Shift Del 1, Frame Shift Ins 1, In Frame Ins 1, 5'UTR 1, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 379/404 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AANAT | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 278/644 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754433122; called by muse, mutect2, varscan2
- ADAM8 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 196/375 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs752531473, COSV69864950; called by muse, mutect2, varscan2
- CCNB1IP1 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV62302535; called by muse, mutect2, varscan2
- FGFR2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 119/588 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs1041970177; called by muse, mutect2, varscan2
- FLT4 | c.985+1G>C p.X329_splice | Splice Site (SNP) | VAF 14/534 reads (3%) | catalogued as COSV99985554; called by muse, mutect2
- MACF1 | c.11006G>A p.R3669H (on ENST00000372915; = p.R1602H on NM_012090.5) | Missense Mutation (SNP) | VAF 523/1101 reads (48%) | catalogued as rs373418940; called by mutect2, varscan2
- MAP4 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 386/815 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as rs879205250; called by muse, mutect2, varscan2
- MITF | c.1087C>T p.R363C (on ENST00000448226 / NM_006722.3; = p.R263C on NM_000248.4) | Missense Mutation (SNP) | VAF 638/1243 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372113245; called by muse, mutect2, varscan2
- MRGPRD | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 102/356 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1031028574; called by muse, mutect2, varscan2
- PCDHGA8 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs1175831509, COSV53935874; called by muse, mutect2, varscan2
- PER1 | c.3759G>C p.E1253D | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.026); catalogued as rs1257474591; called by muse, mutect2
- PHC1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 191/516 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs181118510, COSV70417735; called by muse, mutect2, varscan2
- PLIN1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 119/1162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749463650; called by muse, mutect2, varscan2
- RP1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 94/542 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55123824; called by muse, mutect2, varscan2
- S100A12 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 427/916 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs368146536, COSV64199385; called by muse, mutect2, varscan2
- TPSAB1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs779109021, COSV58781436; called by muse, mutect2
- TSNAXIP1 | c.1447_1449del p.E483del | In Frame Del (DEL) | VAF 201/451 reads (45%) | catalogued as rs780091414; called by mutect2, pindel, varscan2
- UBN1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 217/513 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200541080; called by muse, mutect2, varscan2
- ALS2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 317/987 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.7817T>A p.L2606Q | Missense Mutation (SNP) | VAF 372/843 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSTA | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 63/1092 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH11 | c.10334T>A p.V3445D | Missense Mutation (SNP) | VAF 453/711 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- H1-2 | c.67_68insGGG p.K23delinsRE | In Frame Ins (INS) | VAF 140/715 reads (20%) | called by mutect2, varscan2
- HBG2 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 433/1324 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2012 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 374/1138 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MYO7B | c.4754del p.K1585Rfs*43 | Frame Shift Del (DEL) | VAF 475/1059 reads (45%) | called by mutect2, pindel, varscan2
- NPIPB6 | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHLDB3 | c.1549G>T p.G517* | Nonsense Mutation (SNP) | VAF 305/325 reads (94%) | called by muse, mutect2, varscan2
- POLR1A | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 468/1068 reads (44%) | called by muse, varscan2
- SEC24B | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 595/1216 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLF1 | c.3018dup p.L1007Vfs*20 | Frame Shift Ins (INS) | VAF 449/953 reads (47%) | called by mutect2, pindel, varscan2
- STAM | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 24/825 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2
- TAF1L | c.130A>T p.N44Y | Missense Mutation (SNP) | VAF 334/717 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TEK | c.2209+3del p.X737_splice | Splice Site (DEL) | VAF 119/698 reads (17%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 114/513 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- UTP20 | c.4636T>A p.S1546T | Missense Mutation (SNP) | VAF 287/540 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- VIRMA | c.4006A>T p.N1336Y | Missense Mutation (SNP) | VAF 502/985 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KNSTRN | c.105A>G p.L35= | Silent (SNP) | VAF 56/866 reads (6%) | catalogued as rs768924814; called by muse, mutect2
- SLC6A19 | c.657C>T p.T219= | Silent (SNP) | VAF 301/469 reads (64%) | catalogued as rs764090881; called by muse, mutect2, varscan2
- TWSG1 | c.288G>A p.L96= | Silent (SNP) | VAF 371/401 reads (93%) | called by muse, mutect2, varscan2
- AC103796.1 | n.148-24944T>C | Intron (SNP) | VAF 167/714 reads (23%) | called by muse, mutect2, varscan2
- CACNA1A | c.539+11C>T | Intron (SNP) | VAF 170/323 reads (53%) | catalogued as rs115447563; called by muse, mutect2, varscan2
- CHRD | c.149-69G>A | Intron (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- EMG1 | c.*2966G>A | 3'UTR (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- PRDM1 | c.-66G>A | 5'UTR (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- PSMA1 | c.545-77G>T | Intron (SNP) | VAF 44/89 reads (49%) | called by muse, varscan2
